Surgical pathology report (de-identified scan), TCGA case TCGA-HV-A5A5, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HV-A5A5-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: Pancreatic head cancer

Specimen : CBD, Pancreatic head(LN)

GROSS:

Specimen status: Fresh

Operation: Pylorus preserving pancreaticoduodenectomy
Cholecystectomy

Organs:

Small intestine (25.5 cm in length and 2.5 cm in diameter),
pancreas, partial (7.5 x 5.4 x 3.5 cm),
and common bile duct (5.5 cm in length and 1.0 cm in diameter) in continuity
Gallbladder (8.5 cm in length, 3.4 cm in diameter)

[Pancreas]

Lesion: An ill-defined ovoid mass in pancreatic head to ampullary area

Size: 2.5 x 1.8 x 1.5 cm

Cut surface: Pale tan and firm mass

Extent: Extend to duodenal wall

Resection margins:

Distal pancreatic resection margin: Free of tumor (safety margin: 2.3 cm)

Radial pancreatic margin: Very close to tumor (safety margin: 0.1 cm)

Common bile duct resection margin: Free of tumor

Remaining pancreas: Fibrotic change

[Common bile duct]

Eroded and no mass-like lesion

[Duodenum]

Unremarkable

[Gallbladder]

Mucosa: Dark red to mahogany and velvety

Serosa: Pale pink and smooth

Wall: 0.6 cm in thickness

Frozen section diagnosis

FS1-2, proximal bile duct resection margin: No tumor present

FS3, distal pancreatic resection margin: No tumor present

ICD-0-3

adenocarcinoma, duct, NOS 8500/3

Site: pancreas, head c25.0

ju
12/10/12

[page 2 of 3]
Gross photo: Present

Blocks

T1-8, pancreatic mass x 8
BD, common bile duct x 1
LN1-2, periduodenal lymph nodes x 2
LN3, No. 12 lymph nodes x 1
LN4, No. 13 lymph nodes x 1
FS1-3, frozen permanent x 3

P and D, duodenal resection margin x 2

GB, gallbladder x 1

Microscopic:

Tumor type: Ductal adenocarcinoma

Tumor location: Pancreas

Histologic grade: Moderately differentiated

In situ carcinoma: Not identified

Tumor size: 2.5 x 1.8 x 1.5 cm

Direct extension: Tumor extends beyond the pancreas to duodenum and peripancreatic tissue

Lymphovascular invasion: Present

Perineurial invasion: Present

Surgical margins:

Radial margin: Close to tumor (safety margin: 0.1 cm)

Distal pancreatic resection margin: Free of tumor

Proximal bile duct resection margin: Free of tumor

DIAGNOSIS:

Pancreas, head, pylorus preserving pancreaticoduodenectomy:

Ductal adenocarcinoma, moderately differentiated, infiltrating

Common bile duct, pylorus preserving pancreaticoduodenectomy:

No tumor present

Small intestine, duodenum, pylorus preserving pancreaticoduodenectomy:

Direct tumor extension

[page 3 of 3]
Gallbladder, cholecystectomy:

Chronic cholecystitis

Lymph node, regional, pylorus preserving pancreaticoduodenectomy:

Peripancreatic: Direct tumor extension (2/4)

Periduodenal: No tumor present (0/9)

Lymph node, regional, biopsy:

No. 12: No tumor present (0/3)

No. 13: No tumor present (0/3)

Diagnostic Discrepancy		☒

Source: NCI Genomic Data Commons file 341b3051-2ec0-44e7-abce-04516d66a0a5 (TCGA-HV-A5A5.CB59EF73-6734-4BE4-8BBB-C24359E66FEF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).